CCDI case PBCAXI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/024cbcbe-84cb-477f-9d6a-11779c131c84

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.1 years (5,144 days).

Biospecimens (3 samples)
- Sample 0DN1B3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN1BS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN1D1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
